Somatic mutation profile of tumor specimen TCGA-TS-A7P8-01A (aliquot TCGA-TS-A7P8-01A-11D-A34C-32) from TCGA case TCGA-TS-A7P8, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 80.7 years (29,464 days).
Specimen TCGA-TS-A7P8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f230c67-0c54-4b54-b444-4be7ba6f20fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7P8-10A (Blood Derived Normal), aliquot TCGA-TS-A7P8-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e644bd92-1477-42c6-9acf-3f0ece518759

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Splice Region 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2225G>A p.G742D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs755415626, COSV59205440; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZBTB7A | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59326106; called by muse, mutect2
- AMOTL2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as rs776959994; called by muse, mutect2, varscan2
- MADD | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60620157; called by muse, mutect2
- OR8D4 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1290274076; called by muse, mutect2
- PPP2R2C | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100066903; called by mutect2, varscan2
- PRUNE2 | c.6524C>A p.A2175E | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as COSV65038954; called by muse, mutect2, varscan2
- PSMD8 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.06); catalogued as rs775895233; called by mutect2, varscan2
- RBM10 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs782595848, COSV61309586; called by muse, mutect2
- RNASET2 | c.593A>T p.Q198L | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs926185419, COSV50351505; called by muse, mutect2
- SELENON | c.456C>G p.S152R | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs202188924; ClinVar: uncertain significance; called by mutect2, varscan2
- SF3B3 | c.1601A>G p.N534S | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs532389068; called by muse, mutect2, varscan2
- TTN | c.88763C>T p.A29588V (on ENST00000591111; = p.A22164V on NM_003319.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | PolyPhen benign (0.178); catalogued as rs867830714; called by muse, mutect2, varscan2
- XIRP2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs745669656, COSV99740660; called by muse, mutect2
- ACTL9 | c.274T>A p.S92T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS18 | c.2099A>T p.K700I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ASTN1 | c.3767G>A p.S1256N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.219); called by muse, mutect2
- BRAF | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2
- COL6A3 | c.7399T>C p.S2467P | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- FLRT2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GNE | c.1074A>G p.T358= (on ENST00000396594 / NM_001128227.3; = p.T327= on NM_005476.7 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- GUCY2C | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- KHK | c.728A>C p.D243A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAFG | c.94A>T p.M32L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by muse, mutect2
- MAGEB6B | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- NDUFS7 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR52R1 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- PCDHGA9 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEAR1 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); called by muse, mutect2
- RYR2 | c.8209T>C p.L2737= | Splice Region (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SPAG17 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); called by muse, mutect2
- STARD4 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); called by muse, mutect2
- TAAR9 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2
- TRIM28 | c.2252_2254del p.L751del | In Frame Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- VPS13C | c.6909dup p.K2304* (on ENST00000644861 / NM_020821.3; = p.K2261* on NM_017684.5) | Frame Shift Ins (INS) | VAF 11/109 reads (10%) | called by mutect2, varscan2
- COL12A1 | c.7452C>T p.D2484= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs778626937, COSV59389573, COSV59401302; called by muse, mutect2, varscan2
- COL14A1 | c.4107C>G p.V1369= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- HMG20A | c.801G>A p.L267= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- IGLV3-21 | c.258G>C p.G86= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs745828571; called by muse, mutect2, varscan2
- NBAS | c.2259T>A p.L753= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- NFS1 | c.1170T>C p.Y390= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs560759221; called by muse, mutect2, varscan2
- OXT | c.240C>T p.Y80= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs754339207; called by muse, mutect2, varscan2
- RBFOX1 | c.243C>T p.S81= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as rs1268768787, COSV60951499; called by muse, mutect2, varscan2
- SPAG9 | c.1210C>T p.L404= (on ENST00000262013 / NM_001130528.3; = p.L390= on NM_003971.6) | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- TSGA10IP | c.537C>T p.G179= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1273413628; called by muse, mutect2, varscan2
- POLR3G | c.*96G>A | 3'UTR (SNP) | VAF 7/101 reads (7%) | catalogued as rs1325653011; called by muse, mutect2
